Surgical pathology report (de-identified scan), TCGA case TCGA-YT-A95G, project TCGA-THYM (Thymoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YT-A95G-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Thymus

I- "Thymus":

Thymoma, type 2 of WHO (see also immunohistochemical exam).

II- "Pre-vascular fat":

Free of neoplastic compromise.

Immunohistochemistry Exam:

Morphological features associated with the immunohistochemistry profile support the diagnosis of type B2 thymoma (WHO).

ICD-O-3
Thymoma, type B2 NOS
8584/1
Site: Thymus
6379
JW 3/13/14

Primary Tumor or Site Discrepancy		✓
Not Malignancy History		✓
Local/Secondary/Primary Subtype		✓
Site Is (circle):		
Review of Initials	MFA	Date Reviewed: 11/17/13

Source: NCI Genomic Data Commons file 176d02f3-74a1-41db-a48c-fe154fb3b0c2 (TCGA-YT-A95G.60D44471-E8AB-47FF-BC45-0ECF59E87F81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).